Gene-level copy-number profile of tumor specimen TCGA-AO-A0J3-01A from TCGA case TCGA-AO-A0J3, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.1 years (24,519 days).
Specimen TCGA-AO-A0J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.40c683dc-6337-4e19-9a9d-bad8fcfaa026.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0J3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c456dda-b00c-48e1-bd38-0a4328347f0e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,144; copy number 2: 20,414; copy number 3: 26,780; copy number 4: 8,027; copy number 5: 2,090; copy number 6: 563; copy number 7: 35; copy number 8: 403; copy number 9: 156; copy number 10: 30; copy number 13: 58; copy number 25: 19; copy number 36: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0J3-01A-11D-A036-01): tumor purity 0.89, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 781 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,789,030–153,923,360, 1 gene, copy number 8 (within-gene range 3–8): GATAD2B.
- chr1:153,852,106–155,563,162, 102 genes, copy number 8–13 (within-gene range 3–13) (broad region; genes not listed).
- chr1:166,975,582–167,220,512, 8 genes, copy number 9 (within-gene range 6–9): MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2.
- chr1:172,210,711–173,175,503, 15 genes, copy number 7: AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1.
- chr1:202,590,596–203,024,848, 20 genes, copy number 7 (within-gene range 5–7): SYT2, AC104463.2, AC104463.1, KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6, MGAT4EP, TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A.
- chr1:221,837,334–223,395,465, 30 genes, copy number 10: RNU6-403P, LINC02257, LINC02474, LINC01705, AL356108.1, QRSL1P2, AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185.
- chr8:36,378,069–41,032,998, 99 genes, copy number 25–36 (within-gene range 1–36) (broad region; genes not listed).
- chr11:67,119,263–71,252,577, 141 genes, copy number 8 (broad region; genes not listed).
- chr17:46,193,576–50,756,219, 217 genes, copy number 8 (broad region; genes not listed).
- chr17:56,834,107–60,586,623, 148 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
